Gene-level copy-number profile of tumor specimen C3L-06299-02 from CPTAC case C3L-06299, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.9 years (26,247 days).
Specimen C3L-06299-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 784b9cb2-9aff-421d-b352-115766b98342.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06299-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/05c4ece1-cb44-4306-88f1-22a389deb0c9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 257; copy number 1: 1,245; copy number 2: 12,880; copy number 3: 31,334; copy number 4: 11,046; copy number 5: 921; copy number 6: 86; copy number 7: 23; copy number 8: 439; copy number 9: 15; copy number 10: 149; copy number 13: 307; copy number 14: 152; copy number 15: 53; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,849,674–120,914,238, 4 genes (within-gene range 0–2): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr6:170,615,515–170,738,536, 1 gene (within-gene range 0–2): AL672310.1.
- chr6:170,736,173–170,737,777, 1 gene: AL731684.1.
- chr9:21,398,614–22,214,672, 29 genes: IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:41,310,816–41,480,548, 3 genes: AL354718.2, CDRT15P6, AL354718.1.
- chr9:64,810,865–64,889,063, 4 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,140 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:32,238,679–32,370,321, 1 gene, copy number 8 (within-gene range 2–8): CMTM8.
- chr3:32,391,698–34,677,247, 36 genes, copy number 8–14: CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.1, AC018359.1.
- chr3:35,638,945–41,962,130, 118 genes, copy number 8–15 (within-gene range 2–15) (broad region; genes not listed).
- chr3:67,296,300–70,808,452, 33 genes, copy number 8–14: AC114401.1, SUCLG2, NDUFB4P1, SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, COX6CP6, HMGB1P36, RNU6-281P.
- chr3:79,957,566–81,761,645, 13 genes, copy number 7–16 (within-gene range 2–16): HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P.
- chr3:81,762,706–84,881,924, 7 genes, copy number 8–15 (within-gene range 2–15): AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, SRRM1P2, LINC00971.
- chr3:84,881,984–84,893,379, 1 gene, copy number 10: LINC02025.
- chr3:86,125,216–87,793,629, 17 genes, copy number 9–14: AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P.
- chr3:87,910,220–87,910,345, 1 gene, copy number 10: RNU6ATAC6P.
- chr3:88,601,061–90,261,708, 10 genes, copy number 8–15: NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, RNU6-712P, PROS2P, HSPE1P19.
- chr19:19,385,826–19,979,610, 35 genes, copy number 15: GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2.
- chr19:21,221,645–21,427,577, 11 genes, copy number 13–15 (within-gene range 2–15): AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493.
- chr19:21,804,946–22,317,176, 20 genes, copy number 8–14: ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.1, AC073539.3, ZNF729, BNIP3P31.
- chr19:23,304,991–23,395,471, 1 gene, copy number 14 (within-gene range 2–14): ZNF91.
- chr19:23,380,317–23,512,656, 6 genes, copy number 14: BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P.
- chr19:27,638,483–29,525,752, 41 genes, copy number 7–14 (within-gene range 2–14): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1.
- chr19:29,665,459–31,427,302, 23 genes, copy number 7–13: PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1.
- chr19:31,655,356–33,815,763, 52 genes, copy number 8–13: RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15.
- chr19:37,467,585–37,692,337, 9 genes, copy number 8–13 (within-gene range 2–13): ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30.
- chr19:37,735,833–42,919,563, 270 genes, copy number 7–13 (within-gene range 2–13) (broad region; genes not listed).
- chr19:43,096,456–43,097,360, 1 gene, copy number 8: CEACAMP9.
- chr19:51,594,561–54,473,296, 243 genes, copy number 8 (broad region; genes not listed).
- chr19:54,589,441–54,830,778, 21 genes, copy number 8 (within-gene range 4–8): AC245036.5, LILRA1, AC245036.4, LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3, AC243962.1, LILRP1, AC245128.2, LILRP2, KIR3DL3, AC245128.1, KIR2DL3, KIR2DP1, KIR2DL1, KIR3DP1, KIR2DL4, KIR3DL1.
- chr19:56,219,670–56,823,395, 35 genes, copy number 8–13 (within-gene range 4–13): ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5, AC006116.7, Y_RNA, VN2R17P, AC006116.1, AC006116.3, AC006116.2, AC006116.6, AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835, AC006115.2.
- chr19:56,922,018–58,605,223, 135 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 79. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
